Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9F5, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9F5-01A (Primary Tumor).

ICD O-3

Melanoma, epithelioid & spindle
cell mixed 87X13

Site ^{C69.3} Choroid C69.3

^{path} Uveal tract C69.4
JW 2/16/14

Enucleation of the right eye.

Macroscopy:

The eyeball measures 26 mm in diameter and the posterior optic nerve segment 7 mm, associated with a fragment of adipose tissue of 5 mm. Presence of an extra-scleral nodule measuring 6 mm. At the section, an endo-ocular tumor measuring 20X15 mm main lines is observed. Tumor specimens have been taken for cryopreservation and genetic studies, then the piece has been fixed and included entirely according to 13 tissue blocs.

Microscopy

The tumor observed macroscopically presents the histological features of an uveal melanoma. It is composed of a mix of epithelioid (90%) and fusiform (10%) cells, the latter being predominant. These cells present a large nucleus with prominent nucleolus. The cytoplasm is most often pigmented. Presence of mitotic features (up to 10 mitoses per 10 HPF).

The tumor is developed at the posterior part of the ciliary body which is partially invaded, without extension to the iris. The tumor invades the sclera and present an extra-scleral nodule of 6 mm observed macroscopically.

The tumor is located at distance from the intra-ocular emergence of the optic nerve. Thus the optic nerve on its entire course and the meningeal sheaths are free of tumor. The cut end of the optic nerve is also free of tumor.

Conclusion:

Uveal melanoma composed mainly of fusiform cells.

Tumor size: 20 mm main line.

Focal extension to the ciliary body without infiltration of the iris.

Tumor infiltration of the sclera with an extrascleral nodule of 6 mm.

Optic nerve in its entire course and cut end, and meningeal sheaths free of tumor.

Source: NCI Genomic Data Commons file 804bb2cc-68f2-4ace-93b0-4d36fcda3840 (TCGA-V4-A9F5.540291A7-2C24-4DC4-93B8-8D6C0DFB344C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).